Somatic mutation profile of tumor specimen TCGA-D3-A8GS-06A (aliquot TCGA-D3-A8GS-06A-12D-A372-08) from TCGA case TCGA-D3-A8GS, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 60.1 years (21,959 days).
Specimen TCGA-D3-A8GS-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f160578-1632-41ed-8108-8b779f972fbe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A8GS-10A (Blood Derived Normal), aliquot TCGA-D3-A8GS-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f95f1b6-ebe6-40ee-bbb2-fa96078ca7b5

The open-access MAF lists 249 somatic variants for this specimen: 161 protein-altering or splice-affecting, 82 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 82, Nonsense Mutation 7, Intron 3, Splice Site 2, Splice Region 1, Frame Shift Del 1, 3'Flank 1, IGR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CTNNB1 | c.1147T>G p.W383G | Missense Mutation (SNP) | VAF 13/130 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62690170, COSV62701352, COSV62704397; called by muse, mutect2, varscan2
- NDE1 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 45/109 reads (41%) | catalogued as rs757604577, COSV100707312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.205); catalogued as rs142762485, COSV53196450; called by muse, mutect2, varscan2
- ABCB9 | c.1657G>A p.E553K (on ENST00000280560 / NM_019625.4; = p.E510K on NM_019624.3) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs557925509, COSV99757870; called by muse, mutect2, varscan2
- ACSBG1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV51907003; called by muse, mutect2, varscan2
- ADA2 | c.849T>A p.F283L (on ENST00000262607; = p.F42L on NM_177405.3) | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99376396; called by muse, mutect2, varscan2
- ADAM28 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.832); catalogued as rs867205688, COSV56106450; called by muse, mutect2, varscan2
- ADH1A | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 82/426 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV52924354; called by muse, mutect2, varscan2
- AGXT | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1185670807, COSV100280320; called by muse, mutect2, varscan2
- AK7 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs202192874, COSV50881195; called by muse, mutect2, varscan2
- AMTN | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.067); catalogued as rs1305157886, COSV59490368; called by muse, mutect2, varscan2
- ANK2 | c.4411A>T p.M1471L | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV100003764; called by muse, mutect2, varscan2
- ANK3 | c.849G>A p.M283I | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99781927; called by muse, mutect2, varscan2
- BTBD8 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV100730436; called by muse, mutect2, varscan2
- C1QB | c.343A>C p.K115Q | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV100152815; called by muse, mutect2, varscan2
- C4orf50 | c.684G>T p.M228I (on ENST00000324058; = p.M1460I on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV100136121; called by muse, mutect2, varscan2
- CACNA1G | c.4106G>A p.S1369N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV100662402; called by muse, mutect2, varscan2
- CACNA2D4 | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.584); catalogued as rs1413250024, COSV54960527, COSV99766381; called by muse, mutect2, varscan2
- CCDC57 | c.2407C>T p.P803S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.818); catalogued as COSV101052065; called by muse, mutect2, varscan2
- CCDC63 | c.1063C>T p.Q355* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100370582; called by muse, mutect2, varscan2
- CDC73 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV66465062; called by muse, mutect2
- CDH23 | c.6376C>T p.R2126C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs776269225, COSV99034530; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEACAM6 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 70/276 reads (25%) | catalogued as rs1555821181, COSV99555595; called by muse, varscan2
- CLDN14 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as rs1207027171, COSV100578953; called by muse, mutect2, varscan2
- CNTN3 | c.469T>A p.W157R | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99725844; called by muse, mutect2, varscan2
- COL15A1 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100897502; called by muse, mutect2, varscan2
- COL6A6 | c.2065A>G p.I689V | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as rs751831579, COSV100650828; called by muse, mutect2, varscan2
- CPS1 | c.2264C>T p.S755F | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV51807787; called by muse, mutect2, varscan2
- CSF2RA | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 69/266 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as rs147844397, COSV62624484, COSV62625721; called by muse, mutect2, varscan2
- DCAF6 | c.1834G>A p.D612N (on ENST00000312263 / NM_001349778.1; = p.D632N on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.024); catalogued as COSV100394747, COSV56581994; called by muse, mutect2, varscan2
- DNAH3 | c.9031G>A p.A3011T | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs746811682, COSV54500830; called by muse, mutect2, varscan2
- DNAH7 | c.7046C>T p.S2349F | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204967193, COSV100417102; called by muse, mutect2, varscan2
- DSCAM | c.4937C>T p.S1646L | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV101261384; called by muse, mutect2, varscan2
- DSG1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV99936139, COSV99936462; called by muse, mutect2, varscan2
- DYNC2H1 | c.10481C>T p.P3494L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV62108073; called by muse, mutect2
- DYSF | c.3022G>A p.D1008N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs200943384, COSV99246397; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERICH3 | c.4571C>T p.S1524F | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as rs745496149, COSV58617827; called by muse, mutect2, varscan2
- FAM83B | c.2277G>T p.K759N | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.299); catalogued as COSV100174917; called by muse, mutect2, varscan2
- FBXO43 | c.559del p.E187Kfs*20 | Frame Shift Del (DEL) | VAF 17/97 reads (18%) | catalogued as COSV71053376; called by mutect2, pindel, varscan2
- FCRL5 | c.2921C>T p.A974V | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as COSV100709265; called by muse, mutect2, varscan2
- GHR | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100051850; called by muse, mutect2, varscan2
- GJB4 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375702737, CM073099; called by muse, mutect2, varscan2
- GJB6 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM002605, CM131243, COSV53832458; called by muse, mutect2, varscan2
- GLRB | c.867G>A p.W289* | Nonsense Mutation (SNP) | VAF 37/114 reads (32%) | catalogued as rs1221823218, COSV100030097, COSV52421276; called by muse, mutect2, varscan2
- GNB4 | c.246G>A p.W82* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as COSV99224482; called by muse, mutect2
- GRIN2C | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); catalogued as rs1000741279, COSV99501370; called by mutect2, varscan2
- GRIN2C | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.211); catalogued as rs762668677, COSV99501371; called by muse, mutect2, varscan2
- GRIN3A | c.1855G>A p.D619N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419851518, COSV100701750; called by muse, mutect2, varscan2
- GRM7 | c.1082A>G p.N361S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100738170, COSV63168908; called by muse, mutect2, varscan2
- GRM8 | c.2617G>C p.G873R | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.646); catalogued as COSV100285490; called by muse, mutect2, varscan2
- GSTT2B | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1468149272; called by mutect2, varscan2
- GUCY2C | c.2645C>T p.P882L | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99664083; called by muse, mutect2, varscan2
- HIF3A | c.1664C>T p.S555F (on ENST00000377670 / NM_152795.4; = p.S486F on NM_022462.4) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.11); catalogued as rs950324749, COSV52204917; called by muse, mutect2
- HJURP | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs373002470; called by muse, mutect2, varscan2
- HMCN1 | c.7640G>A p.R2547K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as COSV99634598; called by muse, mutect2
- HSD17B4 | c.2263C>T p.L755F (on ENST00000414835 / NM_001199291.3; = p.L730F on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.081); catalogued as COSV99819698, COSV99820104; called by muse, mutect2, varscan2
- HSPG2 | c.2383T>G p.C795G | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101021129; called by muse, mutect2, varscan2
- HYDIN | c.10165G>A p.G3389R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1482789426, COSV101158164; called by muse, mutect2, varscan2
- IGHV3-20 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 61/232 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); catalogued as rs990678506; called by muse, mutect2, varscan2
- IGSF9B | c.2438G>A p.R813H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.264); catalogued as rs369340509; called by muse, mutect2, varscan2
- IL16 | c.2903C>T p.P968L (on ENST00000302987 / NM_172217.5; = p.P267L on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100268034; called by muse, mutect2, varscan2
- KBTBD3 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1487998743, COSV73241213; called by muse, mutect2, varscan2
- KDR | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV55763691, COSV55775066; called by muse, mutect2, varscan2
- KIF21A | c.4585C>T p.L1529F (on ENST00000361418 / NM_001378440.1; = p.L1516F on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.359); catalogued as COSV100735493; called by muse, mutect2, varscan2
- KLB | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as rs866976112, COSV99962433; called by muse, mutect2, varscan2
- KLHDC7A | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV68771300; called by muse, mutect2, varscan2
- LIFR | c.2107G>T p.G703* | Nonsense Mutation (SNP) | VAF 25/237 reads (11%) | catalogued as COSV54686491, COSV99665753; called by muse, mutect2, varscan2
- LIMS2 | c.259G>A p.V87I (on ENST00000355119 / NM_001161403.3; = p.V111I on NM_017980.4) | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as rs756099594, COSV99760741; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP12 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.465); catalogued as rs199687240, COSV99408278; called by muse, mutect2, varscan2
- LRP1B | c.7523C>T p.S2508F | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1393251553, COSV67193597; called by muse, mutect2, varscan2
- MAGI1 | c.741G>A p.M247I | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.854); catalogued as COSV58334695; called by muse, mutect2, varscan2
- MCTP2 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV63292458; called by muse, mutect2, varscan2
- MEPE | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as COSV100734986; called by muse, mutect2, varscan2
- MFAP5 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1347983798, COSV100848186; called by muse, mutect2
- MRPL16 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs764438212, COSV100276533; called by muse, mutect2, varscan2
- MXRA5 | c.2038G>A p.G680S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV99478880; called by muse, mutect2, varscan2
- MYH2 | c.3001G>A p.E1001K | Missense Mutation (SNP) | VAF 52/252 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99819031; called by muse, mutect2, varscan2
- NAB2 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.431); catalogued as COSV100272771; called by muse, mutect2, varscan2
- NDST4 | c.1267C>T p.H423Y | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as COSV52109225, COSV52126005; called by muse, mutect2, varscan2
- NEDD9 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV101060899; called by muse, mutect2, varscan2
- NMUR1 | c.884T>G p.V295G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as COSV100532124; called by muse, mutect2, varscan2
- NPS | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs865939340, COSV67690454; called by muse, mutect2, varscan2
- NR4A3 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV100432690; called by muse, mutect2, varscan2
- NUP205 | c.5975G>T p.R1992L | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53658536, COSV99607468; called by muse, mutect2, varscan2
- OPHN1 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 17/26 reads (65%) | catalogued as rs774039524, CM054054, COSV100830736; called by muse, mutect2, varscan2
- OR10AG1 | c.287T>A p.L96H | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV100400180; called by muse, mutect2, varscan2
- OR1M1 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV70036628; called by muse, mutect2, varscan2
- OR2A5 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 86/243 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as rs139541008, COSV68738509, COSV68738886; called by muse, mutect2, varscan2
- OR4N2 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs371446325, COSV60056053; called by muse, mutect2, varscan2
- OR5J2 | c.802G>T p.V268L | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100399216; called by muse, mutect2, varscan2
- OR6C1 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65573214, COSV65574627; called by muse, mutect2, varscan2
- OVCH2 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs765597151, COSV101491933; called by muse, mutect2, varscan2
- PAH | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61013690; called by muse, mutect2
- PARP1 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1401471013, COSV100829038; called by muse, mutect2, varscan2
- PCDHA8 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.262); catalogued as COSV100970977; called by muse, mutect2, varscan2
- PCDHB12 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV53394680; called by muse, mutect2, varscan2
- PCDHGA2 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.111); catalogued as rs185685102, COSV99545421; called by muse, mutect2, varscan2
- PCDHGA6 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.542); catalogued as COSV53898537; called by muse, mutect2, varscan2
- PCSK1 | c.1982G>A p.G661E | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.007); catalogued as rs544018373, COSV60734496; called by muse, mutect2, varscan2
- PDCD7 | c.870+1G>A p.X290_splice | Splice Site (SNP) | VAF 8/40 reads (20%) | catalogued as rs1286740710, COSV99200159; called by muse, mutect2, varscan2
- PKNOX2 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs781020037, COSV53541095; called by muse, mutect2, varscan2
- PLTP | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.129); catalogued as COSV99510100; called by muse, mutect2
- PRDM10 | c.1890+1G>T p.X630_splice | Splice Site (SNP) | VAF 31/109 reads (28%) | catalogued as rs1174486262, COSV100456991; called by muse, mutect2, varscan2
- PRH2 | c.190A>T p.N64Y | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV101113338; called by muse, mutect2, varscan2
- RSPH6A | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV99537376; called by muse, mutect2, varscan2
- SAMD9 | c.4468G>A p.E1490K | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV101180349; called by muse, mutect2, varscan2
- SBF2 | c.4433G>A p.C1478Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99815529; called by muse, mutect2, varscan2
- SCN2A | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1174603483, COSV51832149; called by muse, mutect2, varscan2
- SCN3A | c.5964A>T p.K1988N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.036); catalogued as COSV99328264; called by muse, mutect2, varscan2
- SLC27A6 | c.556G>C p.V186L | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0.021); catalogued as COSV99323387; called by muse, mutect2
- SLC4A5 | c.1662G>A p.M554I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV100697958; called by muse, mutect2, varscan2
- SLC9C2 | c.2869G>A p.E957K | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1264791272, COSV100876688, COSV62948142; called by muse, mutect2, varscan2
- SNCAIP | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs776653393, COSV99749865; ClinVar: likely benign; called by muse, mutect2, varscan2
- SORCS3 | c.2989C>T p.H997Y | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100863767, COSV63796584; called by muse, mutect2, varscan2
- SOWAHA | c.1606G>A p.G536R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (1); catalogued as COSV101097722; called by muse, mutect2, varscan2
- SPAG17 | c.5158G>A p.E1720K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); catalogued as COSV100310276; called by muse, mutect2, varscan2
- SPECC1 | c.94A>C p.M32L | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as COSV99822695; called by muse, mutect2, varscan2
- SPICE1 | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1382483715, COSV99871714; called by muse, mutect2, varscan2
- SPOCK3 | c.243G>A p.Q81= | Splice Region (SNP) | VAF 25/153 reads (16%) | catalogued as COSV100693883; called by muse, mutect2, varscan2
- SPTA1 | c.4885T>A p.L1629M | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV100935457, COSV63756942; called by muse, mutect2, varscan2
- SPTBN4 | c.4312C>T p.P1438S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.6); catalogued as COSV100151920; called by muse, mutect2, varscan2
- STK31 | c.2705G>A p.G902E | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1345152620, COSV100669857; called by muse, mutect2, varscan2
- STPG2 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as COSV54790217; called by muse, mutect2, varscan2
- SULT1C2 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99265384; called by muse, mutect2, varscan2
- SV2B | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57701481; called by muse, mutect2, varscan2
- SYCP1 | c.980T>A p.I327N | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV101051154; called by muse, mutect2, varscan2
- SZT2 | c.5995C>T p.P1999S (on ENST00000634258 / NM_001365999.1; = p.P1942S on NM_015284.4) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.889); catalogued as COSV65168844; called by muse, mutect2
- SZT2 | c.5996C>T p.P1999L (on ENST00000634258 / NM_001365999.1; = p.P1942L on NM_015284.4) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.069); catalogued as COSV65168851; called by muse, mutect2, varscan2
- SZT2 | c.7777C>T p.P2593S (on ENST00000634258 / NM_001365999.1; = p.P2536S on NM_015284.4) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV100987611; called by muse, mutect2, varscan2
- TAS1R3 | c.721G>A p.G241S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.855); catalogued as rs1340153313, COSV100229802; called by muse, mutect2
- TBKBP1 | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752435349, COSV100659222; called by muse, mutect2, varscan2
- TMEM131L | c.4735C>T p.R1579C | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs764856494, COSV53647287; called by muse, mutect2, varscan2
- TMEM202 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV58983970; called by muse, mutect2, varscan2
- TNNT2 | c.551A>C p.K184T | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99372498; called by muse, mutect2, varscan2
- TOMM22 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV53266279; called by muse, mutect2, varscan2
- TRHR | c.168G>A p.M56I | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61237025; called by muse, mutect2, varscan2
- TRPV5 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.138); catalogued as COSV99520184; called by muse, mutect2, varscan2
- TTC14 | c.1524C>A p.N508K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV56014484, COSV99870403; called by muse, mutect2, varscan2
- TTC6 | c.281C>A p.P94Q (on ENST00000267368; = p.P1363Q on NM_001310135.3) | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV99942203; called by muse, mutect2, varscan2
- TTN | c.57118G>A p.G19040R (on ENST00000591111; = p.G11616R on NM_003319.4) | Missense Mutation (SNP) | VAF 19/149 reads (13%) | PolyPhen probably damaging (1); catalogued as rs778208423, COSV100626677; called by muse, mutect2, varscan2
- TTN | c.43240C>T p.R14414C (on ENST00000591111; = p.R6990C on NM_003319.4) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | PolyPhen benign (0.001); catalogued as rs1012450335, COSV59880703; called by muse, mutect2, varscan2
- TTN | c.6628G>A p.D2210N (on ENST00000591111; = p.D2164N on NM_003319.4) | Missense Mutation (SNP) | VAF 24/89 reads (27%) | PolyPhen benign (0.001); catalogued as COSV100626679; called by muse, mutect2, varscan2
- TTN | c.5350G>A p.G1784R (on ENST00000591111; = p.G1738R on NM_003319.4) | Missense Mutation (SNP) | VAF 37/101 reads (37%) | PolyPhen probably damaging (1); catalogued as COSV100626681; called by muse, mutect2, varscan2
- TUBB8 | c.983A>C p.E328A | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.949); catalogued as COSV100226186; called by muse, mutect2, varscan2
- UBR4 | c.13111C>T p.P4371S | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100921627; called by muse, mutect2, varscan2
- UBXN10 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1056402681, COSV100907834; called by muse, mutect2, varscan2
- UGT2B15 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 114/597 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV100592433; called by muse, mutect2, varscan2
- UGT3A1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV57098016; called by muse, mutect2, varscan2
- UNC93A | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV100023617; called by muse, mutect2, varscan2
- USH2A | c.11627A>C p.K3876T | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100241257, COSV56326987; called by muse, mutect2
- UVSSA | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs749520493, COSV101104591; called by muse, mutect2, varscan2
- VANGL1 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.229); catalogued as COSV100049379; called by muse, mutect2, varscan2
- VCAN | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1241815847, COSV99427074; called by muse, mutect2, varscan2
- WRN | c.954A>T p.L318F | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99989733; called by muse, mutect2, varscan2
- ZBTB39 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV55631464; called by muse, mutect2, varscan2
- ZFAT | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs749328475, COSV100914883; called by muse, mutect2, varscan2
- ZNF564 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); catalogued as COSV100213265; called by muse, mutect2, varscan2
- ZNF8 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV99544517; called by muse, mutect2, varscan2
- MANEA | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TUBGCP5 | c.2876A>T p.N959I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC100868.1 | c.1953C>T p.G651= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99226749; called by muse, mutect2, varscan2
- ACHE | c.480C>T p.S160= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as COSV99574489; called by muse, mutect2, varscan2
- ADCYAP1 | c.390G>A p.K130= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV99327598; called by muse, mutect2, varscan2
- ADGRE1 | c.1959C>T p.L653= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as rs1460101498, COSV99165741; called by muse, mutect2
- C22orf42 | c.648G>A p.P216= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs140770119, COSV66075248; called by muse, mutect2, varscan2
- C2CD3 | c.4867C>T p.L1623= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100487286; called by muse, mutect2, varscan2
- C4orf17 | c.39G>A p.E13= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as COSV100431081; called by muse, mutect2, varscan2
- CACNA2D2 | c.2139G>A p.E713= (on ENST00000479441 / NM_001174051.3; = p.E706= on NM_006030.4) | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV99818244; called by muse, mutect2, varscan2
- CDC20B | c.702G>A p.L234= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV99697311; called by muse, mutect2, varscan2
- CHST15 | c.573C>T p.F191= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs200698024, COSV100655324; called by muse, mutect2, varscan2
- CKAP4 | c.1131C>T p.L377= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs1337581851, COSV100952514; called by muse, mutect2, varscan2
- CLRN2 | c.381G>A p.P127= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as rs374029760; called by muse, mutect2, varscan2
- CMYA5 | c.3207C>T p.F1069= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV101483716, COSV71406190; called by muse, mutect2, varscan2
- CNTN4 | c.807G>A p.R269= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV61877561; called by muse, mutect2, varscan2
- CPA4 | c.231A>G p.K77= | Silent (SNP) | VAF 42/120 reads (35%) | catalogued as COSV99745296; called by muse, mutect2, varscan2
- CYP4F22 | c.909G>A p.L303= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99513085; called by muse, mutect2, varscan2
- DCTN6 | c.123T>A p.I41= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99645142; called by muse, mutect2, varscan2
- DNAH5 | c.10230G>A p.T3410= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs765000004, COSV54201418; called by muse, mutect2, varscan2
- ELL2 | c.1794G>A p.Q598= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV99427839; called by muse, mutect2, varscan2
- ERICH3 | c.2241G>A p.V747= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as rs1309934565, COSV58616880; called by muse, mutect2
- EWSR1 | c.1665C>T p.P555= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100132009; called by muse, mutect2
- FAT4 | c.5616G>A p.V1872= | Silent (SNP) | VAF 56/155 reads (36%) | catalogued as COSV100629864; called by muse, mutect2, varscan2
- FCRL1 | c.648G>A p.R216= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs763279942, COSV63826818; called by muse, mutect2, varscan2
- FOXD4L5 | c.873G>A p.A291= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV66240701; called by mutect2, varscan2
- GLYATL2 | c.396C>T p.L132= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as rs748599159, COSV99780510; called by muse, mutect2, varscan2
- GPR83 | c.918C>T p.F306= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs745869594, COSV54718114; called by muse, mutect2, varscan2
- GRIA1 | c.2160C>T p.S720= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs1390099560, COSV53602775; called by muse, mutect2, varscan2
- GRM1 | c.379C>T p.L127= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV99268567, COSV99269561; called by muse, mutect2, varscan2
- GUCY1A2 | c.1771C>T p.L591= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV99976431; called by muse, mutect2, varscan2
- HDAC9 | c.1761G>A p.V587= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV101286702, COSV101287163; called by muse, mutect2, varscan2
- INSYN2A | c.927C>T p.P309= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV99732173; called by muse, mutect2, varscan2
- KCND3 | c.765C>T p.I255= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs1557767443, COSV56174087; called by muse, mutect2, varscan2
- KCNG4 | c.1329C>T p.I443= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV57583188; called by muse, mutect2, varscan2
- KIAA0232 | c.3657G>A p.L1219= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100301058; called by muse, mutect2
- LHCGR | c.453C>T p.F151= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV54299618, COSV99683624; called by muse, mutect2, varscan2
- MACF1 | c.7686C>T p.L2562= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as COSV99246399; called by muse, mutect2
- MAP2 | c.5394C>T p.S1798= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs1195076426, COSV99557413; called by muse, mutect2, varscan2
- MARCO | c.243C>T p.F81= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs75633112, COSV59053927; called by muse, mutect2, varscan2
- MGA | c.2277C>T p.S759= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs927722114, COSV99581277; called by muse, mutect2, varscan2
- MGP | c.303G>A p.G101= | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as COSV99967166; called by muse, mutect2, varscan2
- MMP13 | c.165C>T p.I55= | Silent (SNP) | VAF 42/184 reads (23%) | catalogued as COSV99506803; called by muse, mutect2, varscan2
- MSTN | c.486C>T p.P162= | Silent (SNP) | VAF 21/145 reads (14%) | catalogued as rs530890952; called by muse, mutect2, varscan2
- NAB2 | c.588G>C p.G196= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100272772; called by muse, mutect2, varscan2
- NDST3 | c.603G>A p.L201= | Silent (SNP) | VAF 23/231 reads (10%) | catalogued as rs1217377866, COSV99631607; called by muse, mutect2, varscan2
- NEFL | c.1623G>A p.K541= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as COSV99648147; called by muse, mutect2, varscan2
- NPAP1 | c.748C>A p.R250= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs200510789, COSV100274923, COSV61511489; called by muse, mutect2, varscan2
- NR4A3 | c.33C>T p.S11= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs1174879665, COSV100432695; called by muse, mutect2, varscan2
- OR2A25 | c.819C>T p.L273= | Silent (SNP) | VAF 117/381 reads (31%) | catalogued as COSV101376412; called by muse, mutect2, varscan2
- OR4C13 | c.906G>A p.R302= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV101634162, COSV73648869; called by muse, mutect2, varscan2
- OR4E2 | c.138C>T p.I46= | Silent (SNP) | VAF 50/145 reads (34%) | catalogued as COSV57731459; called by muse, mutect2, varscan2
- PCDHAC2 | c.2382G>A p.K794= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV99157374; called by muse, mutect2, varscan2
- PCDHGA2 | c.1374C>A p.S458= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as COSV99545423; called by muse, mutect2, varscan2
- PCNT | c.2826G>A p.L942= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs1204979216, COSV100855975; called by muse, mutect2, varscan2
- PGLYRP4 | c.765G>A p.L255= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV100668507; called by muse, mutect2, varscan2
- PLTP | c.1059C>T p.A353= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99510097; called by muse, mutect2
- POP4 | c.657C>T p.D219= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV55676847; called by muse, mutect2, varscan2
- PPP2R1A | c.204C>T p.A68= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV100436448; called by muse, mutect2, varscan2
- PRKCD | c.1545C>T p.I515= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs782440941, COSV57849737; called by muse, mutect2, varscan2
- QRICH2 | c.3982C>T p.L1328= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs1291461682, COSV99429629; called by muse, mutect2, varscan2
- RAB23 | c.645C>T p.I215= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV100443866; called by muse, mutect2
- RBM8A | c.30T>A p.A10= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100355389; called by muse, mutect2
- RGMA | c.534C>T p.F178= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs1179502287, COSV100224140; called by muse, mutect2, varscan2
- RGS7 | c.484C>A p.R162= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as COSV100470414; called by muse, mutect2, varscan2
- RTN4R | c.1200C>T p.P400= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs779445530, COSV99245197; called by muse, mutect2, varscan2
- SCN3A | c.3117C>T p.I1039= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs1431574068, COSV51806614, COSV51819323; called by muse, mutect2, varscan2
- SLC12A8 | c.1419G>A p.E473= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs1560053474, COSV100103043; called by muse, mutect2, varscan2
- SLC22A3 | c.1227C>T p.P409= | Silent (SNP) | VAF 44/214 reads (21%) | catalogued as COSV99279306; called by muse, mutect2
- SNX29 | c.933C>T p.F311= | Silent (SNP) | VAF 56/140 reads (40%) | catalogued as rs142950576; called by muse, mutect2, varscan2
- SPTBN1 | c.6477G>A p.T2159= | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as rs758704866, COSV61685132, COSV61693565; called by muse, mutect2, varscan2
- STPG2 | c.1233G>A p.R411= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV54794518; called by muse, mutect2, varscan2
- SYCP2L | c.385C>T p.L129= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV99305723; called by muse, mutect2, varscan2
- SYNE1 | c.1698A>C p.T566= (on ENST00000367255 / NM_182961.4; = p.T573= on NM_033071.3) | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV99575970; called by muse, mutect2, varscan2
- SYNE2 | c.5298C>T p.S1766= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs1216620814, COSV100648384; called by muse, mutect2, varscan2
- SYNGR4 | c.459C>T p.S153= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV100785141; called by muse, mutect2, varscan2
- THBS3 | c.2433G>A p.Q811= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs778421173, COSV100104783; called by muse, mutect2, varscan2
- TM6SF1 | c.39C>T p.S13= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs1340642547, COSV99362835; called by muse, mutect2, varscan2
- TRIM41 | c.936G>A p.A312= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs772763077, COSV59322565; called by mutect2, varscan2
- TSKU | c.312C>T p.F104= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs1433062426, COSV100290218; called by muse, mutect2, varscan2
- TSPEAR | c.1650G>A p.V550= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100555251; called by muse, mutect2, varscan2
- UBE2O | c.3363G>A p.E1121= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as COSV100039517; called by muse, mutect2, varscan2
- WDR81 | c.5106C>T p.F1702= (on ENST00000409644 / NM_001163809.2; = p.F651= on NM_152348.4) | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs372716005; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZBTB17 | c.381C>A p.A127= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100999061; called by muse, mutect2, varscan2
- AP001425.1 | chr21:38208241 C>T | 5'Flank (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- HBD | chr11:5232731 C>T | 3'Flank (SNP) | VAF 7/25 reads (28%) | catalogued as rs1267535676, COSV53084090; called by muse, mutect2, varscan2
- MRPL43 | c.529-2167C>T | Intron (SNP) | VAF 36/80 reads (45%) | catalogued as COSV52970751; called by muse, mutect2, varscan2
- TTN | c.10360+3713G>A | Intron (SNP) | VAF 21/150 reads (14%) | catalogued as COSV100616031, COSV59863784, COSV60070291; called by muse, mutect2, varscan2
- TTN | c.10360+2434G>A | Intron (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100626678, COSV100628123; called by muse, mutect2, varscan2
- Unknown | chr21:16194579 G>A | IGR (SNP) | VAF 16/53 reads (30%) | catalogued as rs1434856630; called by muse, mutect2, varscan2
